Somatic mutation profile of tumor specimen C3L-00966-03 (aliquot CPT0101310009) from CPTAC case C3L-00966, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 59.9 years (21,878 days).
Specimen C3L-00966-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8235fe31-254d-4052-8264-10726f0030bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00966-31 (Blood Derived Normal), aliquot CPT0100950002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/932b7280-8694-4ebd-a0ae-f249ac59a6a7

The open-access MAF lists 121 somatic variants for this specimen: 84 protein-altering or splice-affecting, 19 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 19, Intron 10, 3'UTR 7, Frame Shift Del 6, Nonsense Mutation 4, Splice Region 2, Frame Shift Ins 2, Splice Site 2, In Frame Del 2, Nonstop Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.484T>C p.C162R | Missense Mutation (SNP) | VAF 117/409 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1553620313, CM951294, COSV56542418; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCDC33 | c.1945C>T p.L649F | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as rs1374894337; called by muse, varscan2
- CEP152 | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV57858298; called by muse, mutect2, varscan2
- CRB1 | c.1597G>T p.V533L | Missense Mutation (SNP) | VAF 87/433 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs1321368095; called by muse, mutect2, varscan2
- CYP24A1 | c.436G>T p.G146W | Missense Mutation (SNP) | VAF 80/370 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99398477; called by muse, mutect2, varscan2
- CYTH2 | c.271A>C p.N91H | Missense Mutation (SNP) | VAF 53/285 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs776808302; called by muse, mutect2, varscan2
- FAM180B | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as rs535945744, COSV55456310; called by muse, mutect2, varscan2
- IFIT5 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1472046839; called by muse, mutect2
- MFGE8 | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs983065851; called by muse, mutect2, varscan2
- NIPBL | c.2779A>G p.K927E | Missense Mutation (SNP) | VAF 62/361 reads (17%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.039); catalogued as rs142517671; called by muse, mutect2, varscan2
- OR8B8 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 55/272 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.938); catalogued as rs748560249; called by muse, mutect2, varscan2
- PYROXD2 | c.1135+1G>T p.X379_splice | Splice Site (SNP) | VAF 40/209 reads (19%) | catalogued as rs1564794827; called by muse, mutect2, varscan2
- SEMA5B | c.721A>G p.I241V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.05); catalogued as rs1225637203; called by muse, mutect2, varscan2
- SERPINB12 | c.448A>C p.N150H | Missense Mutation (SNP) | VAF 17/207 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV99501820; called by muse, mutect2
- SI | c.4583C>T p.A1528V | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52274128; called by muse, mutect2, varscan2
- SMAP2 | c.772A>G p.I258V | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs774465503; called by muse, mutect2, varscan2
- STEAP1B | c.424A>T p.R142* | Nonsense Mutation (SNP) | VAF 148/450 reads (33%) | catalogued as COSV68346919; called by muse, mutect2, varscan2
- TIMP1 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as rs1413685629; called by muse, mutect2
- UBE3A | c.2071C>G p.P691A | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV51664907; called by muse, mutect2, varscan2
- USP11 | c.1191G>T p.Q397H (on ENST00000218348; = p.Q354H on NM_001371072.1) | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54476380; called by muse, mutect2, varscan2
- UTP3 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1350384336; called by muse, mutect2
- ZHX2 | c.2347G>A p.D783N | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as rs368973670; called by muse, mutect2, varscan2
- ADAMTSL2 | c.1534G>A p.G512R | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- ADRB3 | c.510del p.F170Lfs*5 | Frame Shift Del (DEL) | VAF 68/307 reads (22%) | called by mutect2, pindel, varscan2
- AHCTF1 | c.2614A>T p.K872* (on ENST00000366508; = p.K846* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 16/102 reads (16%) | called by muse, varscan2
- ANKRD61 | c.556A>G p.I186V | Missense Mutation (SNP) | VAF 14/380 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.145); called by muse, mutect2
- AP5S1 | c.557T>C p.F186S | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ARFGEF3 | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- B3GALT4 | c.413T>G p.I138S | Missense Mutation (SNP) | VAF 64/277 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by mutect2, varscan2
- BTAF1 | c.543del p.S182Pfs*14 | Frame Shift Del (DEL) | VAF 22/111 reads (20%) | called by mutect2, pindel, varscan2
- DDIT4 | c.206-2A>G p.X69_splice | Splice Site (SNP) | VAF 19/84 reads (23%) | called by muse, varscan2
- DLL3 | c.245C>G p.A82G | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DOCK3 | c.5968G>T p.G1990W | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- DOCK4 | c.2607del p.K869Nfs*7 | Frame Shift Del (DEL) | VAF 30/106 reads (28%) | called by mutect2, pindel, varscan2
- DOT1L | c.1436C>A p.P479H | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FLT3LG | c.282G>T p.M94I | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FZD8 | c.665_683del p.G222Afs*12 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | called by mutect2, pindel, varscan2
- GPRASP1 | c.4072G>T p.D1358Y | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GRID2 | c.2487G>C p.K829N | Missense Mutation (SNP) | VAF 69/412 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- HIPK1 | c.3524A>G p.Y1175C (on ENST00000369558 / NM_001369806.1; = p.Y781C on NM_181358.2) | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- HLCS | c.1516A>T p.K506* | Nonsense Mutation (SNP) | VAF 105/484 reads (22%) | called by muse, mutect2, varscan2
- ILRUN | c.895T>G p.*299Eext*9 (on ENST00000374023 / NM_024294.4; = p.*233Eext*9 on NM_022758.6) | Nonstop Mutation (SNP) | VAF 26/173 reads (15%) | called by muse, mutect2, varscan2
- ITPR2 | c.5020dup p.I1674Nfs*20 | Frame Shift Ins (INS) | VAF 49/288 reads (17%) | called by mutect2, pindel, varscan2
- LMTK2 | c.3289C>T p.Q1097* | Nonsense Mutation (SNP) | VAF 14/386 reads (4%) | called by muse, mutect2
- LYPD4 | c.540G>C p.G180= | Splice Region (SNP) | VAF 41/172 reads (24%) | called by muse, mutect2
- MAP3K14 | c.1451A>G p.Q484R | Missense Mutation (SNP) | VAF 34/203 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MARCHF7 | c.856A>C p.I286L | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARK3 | c.274T>A p.L92M | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MCF2 | c.190G>T p.V64F | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MEX3B | c.698T>C p.I233T | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.03); called by muse, mutect2
- MINK1 | c.3808G>A p.G1270S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MMP27 | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- MRNIP | c.321G>C p.W107C | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- NKX1-1 | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- NPHP3 | c.3580G>A p.D1194N | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- NTN3 | c.376T>A p.S126T | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR5W2 | c.278C>A p.P93H | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2
- PDZK1IP1 | c.197T>C p.L66P | Missense Mutation (SNP) | VAF 70/319 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- PHF8 | c.1314G>C p.L438F (on ENST00000357988 / NM_001184896.1; = p.L402F on NM_015107.3) | Missense Mutation (SNP) | VAF 72/342 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIWIL1 | c.2134C>A p.L712M | Missense Mutation (SNP) | VAF 46/237 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- PLAU | c.25_45del p.L9_V15del | In Frame Del (DEL) | VAF 55/325 reads (17%) | called by mutect2, pindel
- PYROXD2 | c.1135G>A p.V379M | Missense Mutation (SNP) | VAF 41/217 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- RAPGEF2 | c.1944T>A p.D648E | Missense Mutation (SNP) | VAF 59/273 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RNF185 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RNF6 | c.1846_1855delinsGCACAC p.T616Afs*12 | Frame Shift Del (DEL) | VAF 31/159 reads (19%) | called by pindel, varscan2*
- RYK | c.1182-6T>C | Splice Region (SNP) | VAF 27/151 reads (18%) | called by muse, mutect2, varscan2
- SGF29 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 78/393 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SIAE | c.60A>C p.R20S | Missense Mutation (SNP) | VAF 53/255 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC12A8 | c.1402C>A p.L468I | Missense Mutation (SNP) | VAF 60/292 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SLC9A5 | c.2525C>A p.P842Q | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); called by muse, mutect2
- SNAP47 | c.521C>G p.S174C | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SPA17 | c.214_216del p.H72del | In Frame Del (DEL) | VAF 17/141 reads (12%) | called by mutect2, pindel, varscan2
- SPOUT1 | c.8A>G p.E3G | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- TAAR9 | c.998C>A p.T333N | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- TP53I13 | c.1063G>T p.V355L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TRAK2 | c.2337T>G p.N779K | Missense Mutation (SNP) | VAF 70/340 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM8 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TUBB | c.441G>T p.M147I | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- USH2A | c.14462A>C p.E4821A | Missense Mutation (SNP) | VAF 95/482 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- VGLL2 | c.304C>G p.H102D | Missense Mutation (SNP) | VAF 47/268 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZMYND15 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ZNF713 | c.940dup p.S314Ffs*17 (on ENST00000633730 / NM_001366796.2; = p.S327Ffs*17 on NM_182633.3) | Frame Shift Ins (INS) | VAF 43/195 reads (22%) | called by mutect2, pindel, varscan2
- ZNF814 | c.2312del p.P771Lfs*142 | Frame Shift Del (DEL) | VAF 28/150 reads (19%) | called by mutect2, pindel, varscan2
- ZSWIM8 | c.2359A>G p.S787G | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP30 | c.108G>C p.V36= | Silent (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- ASIC2 | c.33C>T p.S11= | Silent (SNP) | VAF 20/86 reads (23%) | called by muse, varscan2
- ATP6V1B2 | c.885T>C p.V295= | Silent (SNP) | VAF 79/349 reads (23%) | catalogued as COSV52353191; called by muse, mutect2, varscan2
- BMP1 | c.1356A>G p.P452= | Silent (SNP) | VAF 53/291 reads (18%) | called by muse, mutect2, varscan2
- DERPC | c.1132T>C p.L378= | Silent (SNP) | VAF 40/224 reads (18%) | catalogued as rs866642175; called by muse, mutect2, varscan2
- DNAH9 | c.8190A>G p.K2730= | Silent (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2, varscan2
- DNAJC3 | c.768A>G p.K256= | Silent (SNP) | VAF 27/195 reads (14%) | called by muse, mutect2, varscan2
- EDC4 | c.4080C>T p.S1360= | Silent (SNP) | VAF 21/109 reads (19%) | catalogued as rs749360641; called by muse, mutect2, varscan2
- GNPTAB | c.1086T>C p.N362= | Silent (SNP) | VAF 67/323 reads (21%) | catalogued as rs908316825; ClinVar: likely benign; called by muse, mutect2, varscan2
- IFIT5 | c.303C>T p.A101= | Silent (SNP) | VAF 47/264 reads (18%) | called by muse, mutect2, varscan2
- KIAA0753 | c.1158T>C p.C386= | Silent (SNP) | VAF 11/301 reads (4%) | called by muse, mutect2
- KNL1 | c.3678C>A p.S1226= (on ENST00000346991 / NM_170589.5; = p.S1200= on NM_144508.5) | Silent (SNP) | VAF 50/205 reads (24%) | catalogued as COSV100706791; called by muse, mutect2, varscan2
- MBOAT1 | c.912T>C p.D304= | Silent (SNP) | VAF 43/207 reads (21%) | called by muse, mutect2, varscan2
- MRPL46 | c.777G>A p.E259= | Silent (SNP) | VAF 69/373 reads (18%) | catalogued as rs1349002896; called by muse, mutect2, varscan2
- RPAP1 | c.2424C>T p.A808= | Silent (SNP) | VAF 66/266 reads (25%) | catalogued as rs1295176232; called by muse, mutect2, varscan2
- RPAP3 | c.1482A>G p.A494= | Silent (SNP) | VAF 17/207 reads (8%) | catalogued as COSV99139618; called by muse, mutect2
- TPI1 | c.99C>T p.L33= | Silent (SNP) | VAF 22/229 reads (10%) | catalogued as rs375712848; called by muse, mutect2
- UTP23 | c.450T>G p.P150= | Silent (SNP) | VAF 22/107 reads (21%) | called by muse, mutect2, varscan2
- ZNF19 | c.360G>A p.L120= | Silent (SNP) | VAF 50/213 reads (23%) | catalogued as COSV55506959; called by muse, mutect2, varscan2
- ACACB | c.4446+29T>C | Intron (SNP) | VAF 42/176 reads (24%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+3848G>A | Intron (SNP) | VAF 29/129 reads (22%) | called by muse, mutect2, varscan2
- CARD9 | c.*99C>T | 3'UTR (SNP) | VAF 94/513 reads (18%) | called by muse, mutect2, varscan2
- CARHSP1 | c.-7-2325A>G | Intron (SNP) | VAF 52/247 reads (21%) | called by muse, mutect2, varscan2
- CBR1 | c.397+90T>C | Intron (SNP) | VAF 50/260 reads (19%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*358G>A | 3'UTR (SNP) | VAF 54/247 reads (22%) | called by muse, mutect2, varscan2
- CTDSP1 | c.378+273_378+274insTTTT | Intron (INS) | VAF 28/203 reads (14%) | called by mutect2, pindel, varscan2
- GRHPR | c.734+287C>A | Intron (SNP) | VAF 52/224 reads (23%) | catalogued as COSV58942938; called by muse, mutect2, varscan2
- HLX | c.773-58G>A | Intron (SNP) | VAF 48/334 reads (14%) | called by muse, mutect2
- INIP | c.*29T>C | 3'UTR (SNP) | VAF 16/71 reads (23%) | catalogued as rs369116300; called by muse, mutect2, varscan2
- KRBA2 | c.*9640T>G | 3'UTR (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2
- LGALS8 | c.550-81C>T | Intron (SNP) | VAF 71/322 reads (22%) | called by muse, mutect2, varscan2
- LINC02168 | n.154C>A | RNA (SNP) | VAF 37/150 reads (25%) | called by muse, mutect2, varscan2
- LSM14B | c.*183C>A | 3'UTR (SNP) | VAF 45/192 reads (23%) | called by muse, mutect2, varscan2
- RAB11FIP3 | c.903+3607del | Intron (DEL) | VAF 30/132 reads (23%) | catalogued as COSV104386951; called by pindel, varscan2
- SCN4B | c.*2951del | 3'UTR (DEL) | VAF 50/216 reads (23%) | called by mutect2, pindel, varscan2
- TLE3 | c.189+173G>T | Intron (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- ZNF689 | c.*202C>T | 3'UTR (SNP) | VAF 31/165 reads (19%) | called by muse, mutect2, varscan2
